Gene-level copy-number profile of tumor specimen TCGA-UW-A72I-01A from TCGA case TCGA-UW-A72I, project TCGA-KICH (Kidney Chromophobe). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 50.8 years (18,552 days).
Specimen TCGA-UW-A72I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b6029913-04e9-4039-af5b-a4f062b226d7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-UW-A72I-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/90b1c1c6-9ce1-41de-8655-90d671d2ff80

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 38; copy number 1: 21,303; copy number 2: 36,895; copy number 3: 97; copy number 4: 61.

Homozygous deletions (total copy number 0; autosomes only): 38 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,791,397–12,831,410, 3 genes: PRAMEF1, LINC01784, PRAMEF11.
- chr1:12,847,377–13,032,130, 9 genes (within-gene range 0–1): HNRNPCL1, PRAMEF2, PRAMEF4, PRAMEF10, PRAMEF7, RNU6-1072P, PRAMEF29P, PRAMEF6, PRAMEF28P.
- chr1:13,060,869–13,062,229, 1 gene (within-gene range 0–1): HNRNPCL3.
- chr1:248,590,487–248,635,091, 4 genes: OR2T10, Y_RNA, AC098483.2, OR2T11.
- chr2:97,081,098–97,100,874, 4 genes: GPAT2P2, FAHD2B, AC018892.3, RN7SL313P.
- chr2:97,348,899–97,589,965, 9 genes: IGKV3OR2-5, IGKV1OR2-6, IGKV2OR2-7, IGKV2OR2-8, IGKV1OR2-11, AC092683.1, AC092683.2, ANKRD36B, AC017099.1.
- chr10:47,908,064–48,119,455, 8 genes: AC245041.2, NPY4R2, AC245041.1, FAM25C, AGAP12P, RNA5SP315, BMS1P7, PTPN20CP.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 18,959. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
